Surgical pathology report (de-identified scan), TCGA case TCGA-QK-A6V9, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site Emory University - Winship Cancer Inst., specimen TCGA-QK-A6V9-01A (Primary Tumor).

[page 1 of 4]
Document Type: Anat Path Reports

Document Date:

Document Status:

Document Title:

Performed By:

Verified By:

Encounter info:

*** Final Report ***

(Verified)

ICD-O-3
Carcinoma, squamous cell
NOS 8070/3
Site O6CF
Oropharynx NOS
@10.9
path R Palatine tonsil
C09.9
JW 8/2/13

Patient Name:

MRN:

DOB:

Acc #:

Location:

Client:

Submitting Phys:

Copy To Phys:

Gender: M

Collected:

Received:

Reported:

Final Surgical Pathology Report

*** ADDENDUM PRESENT ***

Addendum Diagnosis

The diagnosis is unchanged.

See comment.

Addendum Comment

Tumor shows strong dot-like nuclear signal for HPV 16/18 by in situ hybridization.

Electronically Signed by

Assisted by:

Final Pathologic Diagnosis

A. TONSIL, RIGHT, TONSILLECTOMY, A1FS-A4FS:

- SQUAMOUS CELL CARCINOMA, MODERATELY DIFFERENTIATED, 3.5 CM IN MAXIMUM GROSS DIMENSION.

- DETACHED FRAGMENT OF CARCINOMA PRESENT AT THE INFERIOR MUCOSAL EDGE (SEE SEPARATELY

SUBMITTED MARGIN SPECIMEN BELOW).

- REMAINING MUCOSAL AND DEEP MARGINS FREE OF INVASIVE CARCINOMA OR HIGH GRADE DYSPLASIA.

- NO ANGIOLYMPHATIC OR PERINEURAL INVASION IDENTIFIED.

- SEE SYNOPTIC REPORT AND COMMENT.

B. TONSIL, RIGHT FINAL INFERIOR MARGIN, EXCISION:

- NEGATIVE FOR HIGH GRADE DYSPLASIA OR INVASIVE CARCINOMA.

Comment

[page 2 of 4]
An immunoperoxidase stain for p16 is strongly positive. In situ hybridization for HPV is pending.

Electronically Signed by

Assisted by:

Addendum / Signed Out

Synoptic Worksheet

A. Right radical tonsillectomy:

Specimen:	Oropharynx
Received:	Fresh
Procedure:	Resection, Tonsillectomy
Specimen Integrity:	Fragmented
Specimen Size:	Greatest dimension: 5.0 cm
	Additional dimension: 4.5 cm
	Additional dimension: 3.5 cm
Specimen Laterality:	Right
Tumor Site:	Oropharynx, Palatine tonsil
Tumor Laterality:	Right
Tumor Focality:	Single focus
Tumor Size:	Greatest dimension: 3.5 cm
	Additional dimension: 1.9 cm
	Additional dimension: 1.4 cm
Histologic Type:	Squamous cell carcinoma, conventional
Histologic Grade:	G2: Moderately differentiated
Margins:	Margins uninvolved by invasive carcinoma
	Distance from closest margin: 0.4
	Unit of measurement: cm
	Margin(s): Superior mucosal margin
	Margins uninvolved by carcinoma in situ (includes moderate and severe dysplasia)
Lymph-Vascular Invasion:	Not identified
Perineural Invasion:	Not identified
Lymph Nodes, Extranodal Extension:	Not identified
Pathologic Staging (pTNM):	
TNM Descriptors:	Not applicable
Primary Tumor (pT): Oropharynx:	pT2: Tumor more than 2 cm but not more than 4 cm in greatest dimension
Regional Lymph Nodes (pN): Oropharynx:	pNX: Cannot be assessed
	Number of regional lymph nodes examined: 0
	Number of regional lymph nodes involved: 0
Additional Pathologic Findings:	None identified
Ancillary Studies:	Human papillomavirus associated carcinoma
	Other: P16 positive. HPV ISH pending.

Clinical History

Tonsil cancer.

Specimen(s) Received

A: Right radical tonsillectomy

B: Final inferior margin; ink true margin.

[page 3 of 4]
Gross Description

Specimen A is received fresh for intraoperative consultation, labeled with the patient's name, medical record number and as "right radical tonsillectomy." The specimen consists of a radical tonsillectomy specimen measuring 5.0 x 4.5 x 3.5 cm. Upon receipt in Pathology, the specimen is fragmented into two distinct fragments. The specimen is oriented by the surgeon, He specifies each mucosal margin, which are submitted for frozen section consultation. Arising within the palatine tonsil there is a large polypoid mass measuring 3.5 x 1.9 in surface dimension by a depth of 1.4 cm. The mass is the following distance from each respective mucosal margin: superior 0.4 mm, medial 0.5 cm, inferior 1.0 cm and lateral 2.3 cm. The mass comes within 0.5 cm of the deep resection margin. The mucosal margins are inked as follows: superior, blue; medial, black; lateral, yellow; inferior, orange. The deep margin is inked green. A portion of the tumor is submitted for research purposes. Representative sections are submitted as described in the cassette summary. (Dictated by

Specimen B is received fresh and labeled with the patient's name, medical record number and as "final inferior margin; ink true margin". Received is a small piece of mucosal lined fibrous tissue measuring 1.2 x 0.9 x 0.4 cm with ink on one side. No discrete lesions are identified. The marked surface is re-ink blue and the specimen is serially sectioned and entirely submitted in cassette "B1." (Dictated by

CASSETTE SUMMARY:

A1FS:	Lateral mucosal margin, shave
A2FS:	Inferior mucosal margin, shave
A3FS:	Superior mucosal margin, shave
A4FS:	Medial mucosal margin, shave
A5:	Tumor with respect to medial resection edge and deep margin
A6:	Tumor with respect to medial resection edge and deep margin
A7:	Tumor with respect to superior resection edge and deep margin
A8:	Additional representative mass with respect to deep margin
A9:	Lateral resection edge (yellow) with respect to deep margin
A10,11:	Inferior resection edge (orange) with respect to deep margin

Intraoperative Consult Diagnosis

A1FS: LATERAL MARGIN (FROZEN SECTION): NEGATIVE FOR CARCINOMA.
A2FS: INFERIOR MARGIN (FROZEN SECTION): RARE DETACHED FOCUS OF CARCINOMA.
A3FS: SUPERIOR MARGIN (FROZEN SECTION): NEGATIVE FOR CARCINOMA.
A4FS: MEDIAL MARGIN (FROZEN SECTION): NEGATIVE FOR CARCINOMA.
Frozen section results were communicated to the surgical team and were repeated back by
on

Pathologist:

Microscopic Description

Microscopic examination performed.

ANALYTE SPECIFIC REAGENT (ASR) DISCLAIMER:

Some of the above tests may use Class I ASRs. These tests were developed and their performance characteristics determined by They have not been cleared or approved by the Federal Drug Administration (FDA). The FDA does not require these tests to go through premarket FDA review. These tests are used for clinical purposes and should not be regarded as investigational or for research. is certified under the Clinical Laboratory Improvement Amendments (CLIA) as qualified to perform high complexity clinical laboratory testing.

[page 4 of 4]
Pr. or Malignancy History		☒
Case is (check):	☒ CHALLENGE / ☐ DISQUALIFIED	

Source: NCI Genomic Data Commons file 30f0de11-cb1d-4335-a1e4-6c2ccde8be01 (TCGA-QK-A6V9.2286118E-FACB-407E-8F84-2D6EF71C1DE9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).